Surgical pathology report (de-identified scan), TCGA case TCGA-5P-A9K4, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University Hospital Erlangen, specimen TCGA-5P-A9K4-01A (Primary Tumor).

ICD-O-3
Carcinoma, papillary renal cell 8260/3
Site: (L) Kidney NOS C64.9
JJS 6/13/14

Papillary Renal Cell Carcinoma, Type I, moderately differentiated

Stage: pT1b, R0

Grade: GII

ICD-O-Code: 8260/3

Laterality = (L)

Source: NCI Genomic Data Commons file b07c54a5-527f-4c4e-a0f0-a72d49067c28 (TCGA-5P-A9K4.13D31CA3-FECE-432E-B292-CF368DFDADE5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).